Gene-level copy-number profile of tumor specimen ALCH-ADI6-TTP1-A from ALCHEMIST case ALCH-ADI6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,842 days).
Specimen ALCH-ADI6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 421d2be3-8b86-4b27-a2dd-5338727cf338.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADI6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/faf6b137-3ede-44b8-8353-1f368e9722eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 90; copy number 2: 57,905; copy number 3: 364; copy number 4: 35; copy number 5: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:191,834,310–192,776,899, 9 genes, copy number 5: CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2.

Autosomal genes at a single copy (total copy number 1): 90. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
